Surgical pathology report (de-identified scan), TCGA case TCGA-WN-A9G9, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of Kansas, specimen TCGA-WN-A9G9-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

NAME: _____ SURG PATH #:
MR #: _____ SPECIMEN CLASS:
BILLING #: _____ ALT ID #:
LOCATION: _____ DATE OF PROCEDURE:
AGE: _____ SEX: M DATE RECEIVED:
DOB: _____ TIME RECEIVED:
PHYSICIAN: _____ DATE OF REPORT:
COPY TO: _____ DATE OF PRINTING:

Material Received:

A: renal mass left - stitch deep margin
B: peri tumor fat

History:

year-old male with history of a renal mass.

*IED 03
Carcinoma, papillary renal cell 82643
Site: @ Kidney NOS C64.9
JW 6/13/14*

Final Diagnosis:

- A. Kidney, "left renal mass", partial nephrectomy:
Renal cell carcinoma, papillary type, Fuhrman grade 3. See comment.
- B. Fibroadipose tissue, "peri tumor fat", biopsy:
There is no evidence of malignancy.

Comment:

Specimen Type: Partial nephrectomy
Laterality: Left
Tumor Site: Upper pole
Focality: Unifocal
Tumor Size: 5.5 x 4.5 x 3.9 cm
Histologic Type: Papillary renal cell carcinoma, type 2
Histologic (Fuhrman) Grade: Grade 3
Macroscopic Extent of Tumor: Tumor is confined to the kidney
Surgical Margins: Margins uninvolved by invasive carcinoma
Adrenal Gland: N/A
Large vessel invasion (renal vein, vena cava): N/A
Microvascular invasion: Not identified
Lymph Nodes: N/A
Pathologic Staging: pT1b NX

Renal Cell Carcinoma

Primary Tumor (pT)

pT1b: Tumor more than 4 cm but not more than 7 cm in greatest dimension, limited to the kidney

Regional Lymph Nodes (pN)

pNX: Cannot be assessed

Distant Metastasis (pM)

MR #:

Page 1 of 2

SURGICAL PATHOLOGY REPORT

Date of Printing:

Order Number:

[page 2 of 2]
NAME:
MR #:

SURG PATH #:
ALT ID #:

pMX: Cannot be assessed

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Pursuant to the _____ this case has been concurrently reviewed by the following pathologist: _____ who agrees with the above diagnosis.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Electronically Signed Out By

Interpreted by:

Gross Description:

A. Received fresh labeled with the patient's name and "renal mass" is a 5.5 x 4.5 x 4.2 cm partial nephrectomy specimen. The margin is designated by a suture. The margin is inked black and the capsule is inked blue. The specimen is serially sectioned to reveal a 5.5 x 4.5 x 3.9 cm encapsulated yellow gold mass that is adjacent to the margin but not extending through the margin grossly. The mass is also adjacent to the blue capsule. The uninvolved kidney is tan-brown, pale and unremarkable. A representative section of the mass to the margin is submitted in cassette A1FS for frozen and permanent sections. Additional representative sections are submitted in cassettes A2-A7.

B. Received in formalin labeled with the patient's name and "peritumor fat" are multiple tan-pink irregular unoriented tissue fragments. No discrete mass is identified grossly. The specimen is submitted entirely in cassettes B1-B3.

Intraoperative Consultation:

A1FS, kidney, "renal mass":

Margins free of involvement.

Renal cell carcinoma, favor papillary type/.

Date of Printing:

MR #:
SURGICAL PATHOLOGY REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file 30f6bce3-5bd4-44cf-9b02-dfd8873685ed (TCGA-WN-A9G9.A6D9B05F-99EE-4E2F-9321-277EC714A514.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).